FM case AD15827 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/d500e0fd-821d-4947-8f45-a40fbd6d3bd0

Female, 72.0 years: Duct adenocarcinoma, NOS (ICD-O-3 8500/3) of the pancreas; metastasis biopsied or resected from the liver. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
